Somatic mutation profile of tumor specimen MP2PRT-PAVAHL-TMP1-A (aliquot MP2PRT-PAVAHL-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVAHL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,851 days).
Specimen MP2PRT-PAVAHL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1f09ba4-147d-4109-b1ea-8f718fca5932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAHL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAHL-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c018d84-ea82-49ae-a89d-4f105ebc169b

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 6, Nonsense Mutation 4, Nonstop Mutation 1, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60623092; called by muse, mutect2, varscan2
- CHD1 | c.3865C>T p.L1289F | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV52340310; called by muse, mutect2, varscan2
- DPH1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777523242; called by muse, mutect2, varscan2
- FYB2 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs1172090933; called by muse, mutect2, varscan2
- GTPBP3 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 197/526 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50196125; called by muse, mutect2, varscan2
- MGA | c.3568C>T p.Q1190* | Nonsense Mutation (SNP) | VAF 131/307 reads (43%) | catalogued as COSV54951883; called by muse, mutect2, varscan2
- PKHD1L1 | c.10211C>T p.S3404L | Missense Mutation (SNP) | VAF 12/355 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs1017905059, COSV65749037; called by muse, mutect2
- POLE | c.5988C>G p.F1996L | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756828876; called by muse, mutect2, varscan2
- PXN | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 87/204 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs201674533, COSV57217666, COSV99935791; called by muse, mutect2, varscan2
- RPL7 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1452422554, COSV53581960; called by muse, mutect2, varscan2
- TAS2R5 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1482588189; called by muse, mutect2, varscan2
- UACA | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs536787451; called by muse, mutect2, varscan2
- ZDHHC8 | c.1402del p.H468Mfs*168 | Frame Shift Del (DEL) | VAF 263/741 reads (35%) | catalogued as COSV100273123; called by pindel, varscan2
- ZFHX4 | c.5257G>T p.D1753Y | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51505633; called by muse, mutect2, varscan2
- ZSWIM9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 240/512 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as rs780754611; called by muse, mutect2, varscan2
- AMPD1 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 96/226 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ARHGEF12 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- BAHCC1 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHD1 | c.4522C>T p.Q1508* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- CNOT3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 202/430 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRTAC1 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- CWF19L2 | c.2406G>C p.L802F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CYP2A7 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DCTN2 | c.814G>C p.D272H (on ENST00000548249 / NM_001261413.2; = p.D277H on NM_006400.4) | Missense Mutation (SNP) | VAF 94/262 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNASE2B | c.999C>G p.F333L | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETV6 | c.399_400insCC p.F134Pfs*76 | Frame Shift Ins (INS) | VAF 142/401 reads (35%) | called by mutect2, pindel, varscan2
- FAM193B | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 143/458 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FAM193B | c.1585G>C p.D529H | Missense Mutation (SNP) | VAF 143/418 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FAT3 | c.9145C>G p.L3049V | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FRG2B | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- GFRA2 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2IP | c.3129C>G p.F1043L | Missense Mutation (SNP) | VAF 121/360 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IQCA1 | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- JAG2 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 161/544 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- KDM3A | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2
- OR51Q1 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHPRH | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TCF20 | c.4607C>G p.S1536* | Nonsense Mutation (SNP) | VAF 264/592 reads (45%) | called by muse, mutect2, varscan2
- TCF20 | c.4445C>T p.S1482F | Missense Mutation (SNP) | VAF 258/552 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TMPRSS5 | c.1373G>C p.*458Sext*30 | Nonstop Mutation (SNP) | VAF 35/284 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 167/352 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF98 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 8/206 reads (4%) | called by muse, mutect2
- BLM | c.1437C>T p.F479= | Silent (SNP) | VAF 100/274 reads (36%) | catalogued as COSV61921506, COSV61928073; called by muse, mutect2, varscan2
- MAPK8IP1 | c.366G>A p.P122= | Silent (SNP) | VAF 137/420 reads (33%) | catalogued as rs899230805; called by muse, mutect2, varscan2
- SLC7A14 | c.660G>C p.L220= | Silent (SNP) | VAF 160/365 reads (44%) | called by muse, mutect2, varscan2
- SSH1 | c.294G>A p.E98= | Silent (SNP) | VAF 103/234 reads (44%) | catalogued as rs773933259, COSV58459479; called by muse, mutect2, varscan2
- STYK1 | c.114C>T p.L38= | Silent (SNP) | VAF 18/440 reads (4%) | catalogued as COSV50015454; called by muse, mutect2
- ZNF615 | c.2037G>A p.P679= | Silent (SNP) | VAF 126/282 reads (45%) | catalogued as rs146634089, COSV65034440; called by muse, mutect2, varscan2
- ARRDC2 | c.-1G>C | 5'UTR (SNP) | VAF 143/304 reads (47%) | catalogued as COSV99717015; called by muse, mutect2, varscan2
- HNF4A | c.1129+32G>C | Intron (SNP) | VAF 19/451 reads (4%) | called by muse, mutect2
